Somatic mutation profile of tumor specimen C3N-02061-02 (aliquot CPT0134310011) from CPTAC case C3N-02061, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 67.8 years (24,760 days).
Specimen C3N-02061-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6235be88-567e-4f37-b566-63078032f7fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02061-71 (Blood Derived Normal), aliquot CPT0134420002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bfc4d5d4-1150-4ee7-8dd3-f187e2a042bd

The open-access MAF lists 609 somatic variants for this specimen: 415 protein-altering or splice-affecting, 120 silent, 74 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 286, Silent 120, Frame Shift Del 74, Intron 38, Nonsense Mutation 21, Frame Shift Ins 17, 3'UTR 15, 5'UTR 11, Splice Region 9, In Frame Del 6, RNA 5, 3'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANO5 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 65/298 reads (22%) | catalogued as rs749645231, CM117897; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 110/500 reads (22%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- DICER1 | c.4130del p.P1377Lfs*2 | Frame Shift Del (DEL) | VAF 37/182 reads (20%) | catalogued as rs34678453; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FBXW7 | c.1514G>A p.R505H (on ENST00000281708 / NM_001349798.2; = p.R425H on NM_018315.5) | Missense Mutation (SNP) | VAF 82/380 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519896, COSV55901126, COSV55908371, COSV55911517; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- MYO5B | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 130/616 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1555648414, CM102932; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 42/218 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PKLR | c.1269G>A p.A423= | Splice Region (SNP) | VAF 92/411 reads (22%) | catalogued as rs774652817, CS971876, CS971877, COSV61361414; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PLA2G6 | c.2239C>T p.R747W | Missense Mutation (SNP) | VAF 126/516 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121908687, CM090726; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 60/319 reads (19%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.968dup p.N323Kfs*2 | Frame Shift Ins (INS) | VAF 42/206 reads (20%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- SLC16A1 | c.41dup p.D15Rfs*34 | Frame Shift Ins (INS) | VAF 43/220 reads (20%) | catalogued as rs606231309; ClinVar: pathogenic; called by mutect2, varscan2
- AASDH | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 48/302 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs776839976, COSV99221755; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2014G>A p.V672M | Missense Mutation (SNP) | VAF 121/466 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.599); catalogued as rs1048937531; called by muse, mutect2, varscan2
- ADAR | c.2360C>T p.A787V | Missense Mutation (SNP) | VAF 95/392 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs367868255; called by muse, mutect2, varscan2
- ADARB2 | c.1789C>T p.R597C | Missense Mutation (SNP) | VAF 39/228 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1323817220, COSV101184543, COSV67182245; called by muse, mutect2, varscan2
- ADCY4 | c.2297C>T p.S766L | Missense Mutation (SNP) | VAF 38/218 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as COSV60253633; called by muse, mutect2, varscan2
- ADGRB1 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1311729255, COSV100030155; called by muse, mutect2, varscan2
- ADGRE2 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 40/236 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as rs374318452; called by muse, mutect2, varscan2
- ADGRG2 | c.1192G>A p.A398T (on ENST00000379869 / NM_001079858.3; = p.A395T on NM_005756.4) | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.838); catalogued as COSV61337791; called by muse, mutect2, varscan2
- AFF2 | c.2609G>A p.R870H | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs782806508, COSV53991574; called by muse, mutect2, varscan2
- AHNAK2 | c.16787G>A p.G5596D | Missense Mutation (SNP) | VAF 76/310 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.255); catalogued as rs764335055, COSV60917997; called by muse, mutect2, varscan2
- AKAP1 | c.66G>C p.W22C | Missense Mutation (SNP) | VAF 76/292 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.086); catalogued as COSV58471981; called by muse, mutect2, varscan2
- AKAP8 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 80/314 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as rs755984203; called by muse, mutect2, varscan2
- AMN | c.133G>A p.G45S | Missense Mutation (SNP) | VAF 106/470 reads (23%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.976); catalogued as rs757059886, COSV54487811; called by muse, mutect2, varscan2
- ANK3 | c.7288A>G p.I2430V | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs535775688; called by muse, mutect2, varscan2
- ANXA13 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.167); catalogued as rs1158464506, COSV51626318; called by muse, mutect2
- AOC1 | c.2222del p.P741Lfs*54 | Frame Shift Del (DEL) | VAF 12/61 reads (20%) | catalogued as rs999461756; called by mutect2, pindel
- ARHGAP4 | c.498G>A p.T166= | Splice Region (SNP) | VAF 50/202 reads (25%) | catalogued as COSV100603790, COSV63130724; called by muse, mutect2, varscan2
- ARHGEF17 | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 45/200 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs200132734; called by muse, mutect2, varscan2
- BMP3 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 100/452 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs138962672; called by muse, mutect2, varscan2
- BMP8B | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 61/224 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0.011); catalogued as rs775912651, COSV62927859; called by muse, mutect2, varscan2
- C19orf57 | c.1529C>T p.A510V | Missense Mutation (SNP) | VAF 50/221 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.101); catalogued as rs1483905431; called by muse, mutect2, varscan2
- C6 | c.828del p.S277Afs*43 | Frame Shift Del (DEL) | VAF 94/538 reads (17%) | catalogued as rs372345940, CD982526, COSV54718324; called by mutect2, pindel, varscan2
- CCDC175 | c.1895del p.N632Tfs*8 | Frame Shift Del (DEL) | VAF 6/48 reads (13%) | catalogued as rs1198843594; called by mutect2, varscan2
- CCER1 | c.1151del p.L384* | Frame Shift Del (DEL) | VAF 26/137 reads (19%) | catalogued as rs1565866062; called by mutect2, pindel, varscan2
- CD46 | c.188A>G p.K63R | Missense Mutation (SNP) | VAF 81/337 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.373); catalogued as COSV100522817; called by muse, mutect2, varscan2
- CD6 | c.1339G>A p.A447T | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs928351755, COSV57835872; called by muse, mutect2, varscan2
- CDH8 | c.2090G>A p.R697H | Missense Mutation (SNP) | VAF 49/259 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766629695, COSV54858441, COSV99076733; called by muse, mutect2, varscan2
- CEP131 | c.1827_1828del p.K610Gfs*25 (on ENST00000269392 / NM_001319228.2; = p.K607Gfs*25 on NM_014984.4) | Frame Shift Del (DEL) | VAF 54/358 reads (15%) | catalogued as rs1324079041; called by pindel, varscan2
- CEP68 | c.1490C>T p.S497L | Missense Mutation (SNP) | VAF 87/317 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as rs747138066, COSV53127372; called by muse, mutect2, varscan2
- CHRNA7 | c.1281del p.E428Rfs*60 | Frame Shift Del (DEL) | VAF 14/89 reads (16%) | catalogued as rs778298112; called by mutect2, varscan2
- CNBD2 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1420088490; called by muse, mutect2, varscan2
- CNTN6 | c.2759G>A p.C920Y | Missense Mutation (SNP) | VAF 70/293 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV63166226; called by muse, mutect2, varscan2
- COIL | c.587del p.K196Rfs*13 | Frame Shift Del (DEL) | VAF 46/162 reads (28%) | catalogued as rs748995811; called by mutect2, varscan2
- COL26A1 | c.332C>T p.T111M (on ENST00000313669 / NM_001278563.3; = p.T109M on NM_133457.4) | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs759733265; called by muse, mutect2, varscan2
- COL7A1 | c.5927G>A p.R1976Q | Missense Mutation (SNP) | VAF 49/384 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.919); catalogued as rs982433923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPA4 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 59/347 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as rs769830808, COSV55982757; called by muse, mutect2, varscan2
- CPT1C | c.2128G>A p.G710R | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200603571; called by muse, mutect2, varscan2
- CRYBG2 | c.1178del p.K393Rfs*16 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | catalogued as rs747248693; called by mutect2, varscan2
- DAB1 | c.1385G>A p.R462H (on ENST00000371231; = p.R429H on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as rs144347021, COSV64692596; called by muse, mutect2, varscan2
- DAB1 | c.1048G>A p.V350I (on ENST00000371231; = p.V317I on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.381); catalogued as rs762774818, COSV100976758; called by muse, mutect2, varscan2
- DAB2IP | c.3352G>A p.A1118T (on ENST00000408936; = p.A1090T on NM_032552.3) | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.146); catalogued as rs1564237169, COSV52255051; called by muse, mutect2
- DCX | c.-22-6G>A | Splice Region (SNP) | VAF 40/209 reads (19%) | catalogued as COSV57566464; called by muse, mutect2, varscan2
- DDR1 | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs201876615; called by muse, mutect2, varscan2
- DDX43 | c.1092del p.G365Vfs*2 | Frame Shift Del (DEL) | VAF 28/131 reads (21%) | catalogued as rs1424884917, COSV64836411; called by mutect2, varscan2
- DENND2B | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 76/351 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1258045916, COSV58203528; called by muse, mutect2, varscan2
- DENND6A | c.1074dup p.A359Cfs*2 | Frame Shift Ins (INS) | VAF 45/173 reads (26%) | catalogued as rs34959359; called by mutect2, varscan2
- DHX30 | c.811G>A p.V271M (on ENST00000445061 / NM_138615.3; = p.V232M on NM_014966.3) | Missense Mutation (SNP) | VAF 61/246 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.647); catalogued as COSV100820062; called by muse, mutect2, varscan2
- DMBT1 | c.7375G>A p.G2459R (on ENST00000338354 / NM_001377530.1; = p.G1702R on NM_004406.3) | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs777578701, COSV57554139; called by muse, mutect2, varscan2
- DNAH17 | c.9695G>A p.R3232H | Missense Mutation (SNP) | VAF 95/415 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.725); catalogued as rs141968026; called by muse, mutect2, varscan2
- DNAH3 | c.3586C>T p.Q1196* | Nonsense Mutation (SNP) | VAF 45/174 reads (26%) | catalogued as COSV99771365; called by muse, mutect2, varscan2
- DOCK3 | c.1084C>T p.R362* | Nonsense Mutation (SNP) | VAF 19/232 reads (8%) | catalogued as COSV56532621, COSV99808755; called by muse, mutect2
- DOCK6 | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); catalogued as rs756004393; called by muse, mutect2, varscan2
- DOT1L | c.299C>T p.T100M | Missense Mutation (SNP) | VAF 83/312 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs781606489, COSV67107693; called by muse, mutect2, varscan2
- DSCAML1 | c.3997C>T p.R1333W (on ENST00000321322; = p.R1273W on NM_020693.4) | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs772494685, COSV58393888; called by muse, mutect2, varscan2
- DTX1 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 74/393 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.324); catalogued as rs1314428665; called by muse, mutect2, varscan2
- E2F1 | c.1303del p.L435Wfs*58 | Frame Shift Del (DEL) | VAF 25/111 reads (23%) | catalogued as rs1409099723, COSV55776265; called by mutect2, pindel, varscan2
- EIF4A2 | c.854A>G p.K285R | Missense Mutation (SNP) | VAF 54/271 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV56218171; called by muse, mutect2, varscan2
- ELFN2 | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.32); catalogued as rs778030367, COSV68744512; called by muse, mutect2, varscan2
- ELK1 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 68/301 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as rs1569338557; called by muse, mutect2, varscan2
- EPHA5 | c.2986G>A p.A996T | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs1238493512, COSV56637556; called by muse, mutect2
- EPM2AIP1 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 73/315 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1209120917; called by muse, mutect2, varscan2
- ERICH3 | c.2600C>T p.A867V | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV58604760; called by muse, mutect2, varscan2
- ESS2 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 51/201 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs146164647; called by muse, mutect2, varscan2
- EVPL | c.349_351del p.K117del | In Frame Del (DEL) | VAF 36/132 reads (27%) | catalogued as rs762534558; called by mutect2, pindel, varscan2
- EXOC2 | c.1876G>A p.V626M | Missense Mutation (SNP) | VAF 50/267 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs756375300, COSV100033514; called by muse, mutect2, varscan2
- EXOC3L2 | c.2153G>A p.R718H | Missense Mutation (SNP) | VAF 96/415 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752805504, COSV52972268; called by muse, mutect2, varscan2
- FAM222B | c.1655G>A p.R552Q | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.992); catalogued as rs771651778, COSV57928144; called by muse, mutect2, varscan2
- FANK1 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs748738165, COSV64156251; called by muse, mutect2, varscan2
- FAT4 | c.13143C>A p.S4381R | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.497); catalogued as COSV58683808, COSV58683821; called by muse, mutect2, varscan2
- FBXL19 | c.614del p.P205Rfs*26 | Frame Shift Del (DEL) | VAF 26/110 reads (24%) | catalogued as rs745385709; called by mutect2, varscan2
- FHOD1 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 62/243 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs940031284; called by muse, mutect2, varscan2
- FLG | c.447del p.R151Gfs*43 | Frame Shift Del (DEL) | VAF 146/711 reads (21%) | catalogued as COSV64237488; called by mutect2, pindel, varscan2
- FLNC | c.1936G>A p.D646N | Missense Mutation (SNP) | VAF 68/335 reads (20%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.777); catalogued as rs372668691; called by muse, mutect2, varscan2
- FOSL2 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as rs1398906591; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 36/194 reads (19%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- FUS | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 87/448 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.976); catalogued as rs1415220872; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GADL1 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs539785730, COSV56978645; called by muse, mutect2, varscan2
- GKN1 | c.481dup p.Y161Lfs*36 | Frame Shift Ins (INS) | VAF 51/220 reads (23%) | catalogued as rs759880395; called by mutect2, varscan2
- GLG1 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 50/202 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.051); catalogued as rs780105388; called by muse, mutect2
- GNAZ | c.239C>A p.S80* | Nonsense Mutation (SNP) | VAF 98/447 reads (22%) | catalogued as COSV50738087; called by muse, mutect2, varscan2
- GOT1L1 | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 47/228 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.06); catalogued as COSV100294348; called by muse, varscan2
- GRIA1 | c.2611G>A p.G871S | Missense Mutation (SNP) | VAF 116/513 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs139089198, COSV53588447; called by muse, mutect2, varscan2
- H2BC7 | c.38del p.K13Rfs*7 | Frame Shift Del (DEL) | VAF 44/213 reads (21%) | catalogued as rs1561982611; called by mutect2, pindel, varscan2
- HACD4 | c.689del p.K230Rfs*45 | Frame Shift Del (DEL) | VAF 82/344 reads (24%) | catalogued as rs768797944; called by mutect2, varscan2
- HCLS1 | c.1360G>A p.V454I | Missense Mutation (SNP) | VAF 56/276 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1465958929, COSV57523115; called by muse, mutect2, varscan2
- HDAC3 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 75/346 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as rs748543297, COSV59497879; called by muse, mutect2, varscan2
- HECTD4 | c.1256A>G p.Y419C | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs753651883; called by muse, mutect2, varscan2
- HIPK2 | c.3151C>T p.R1051C | Missense Mutation (SNP) | VAF 66/294 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs369198128; called by muse, mutect2, varscan2
- HIVEP1 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as rs762780605, COSV65102174; called by muse, mutect2
- HLA-DQB2 | c.431G>A p.C144Y | Missense Mutation (SNP) | VAF 78/281 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759100922, COSV68614333; called by muse, mutect2, varscan2
- HNRNPL | c.1010del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs767148651; called by mutect2, varscan2
- HOXC13 | c.131del p.G44Vfs*95 | Frame Shift Del (DEL) | VAF 23/82 reads (28%) | catalogued as rs775869095; called by mutect2, pindel, varscan2
- HSF4 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 112/437 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs1039305720; called by muse, mutect2, varscan2
- IGF2 | c.686dup p.E230Rfs*50 (on ENST00000434045 / NM_001127598.3; = p.E174Rfs*50 on NM_000612.6) | Frame Shift Ins (INS) | VAF 10/40 reads (25%) | catalogued as rs755455183; ClinVar: uncertain significance; called by mutect2, varscan2
- IL1RAP | c.864del p.K288Nfs*15 | Frame Shift Del (DEL) | VAF 37/160 reads (23%) | catalogued as rs780458834, COSV50762431; called by mutect2, pindel, varscan2
- ILDR2 | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 57/257 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.053); catalogued as rs772962588; called by muse, mutect2, varscan2
- IQGAP1 | c.4189C>T p.R1397W | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs963485476, COSV99185465; called by muse, mutect2, varscan2
- IVL | c.1144C>T p.Q382* | Nonsense Mutation (SNP) | VAF 55/243 reads (23%) | catalogued as rs1203503868; called by muse, mutect2, varscan2
- KCNA5 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 51/253 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.225); catalogued as COSV52903646; called by muse, mutect2, varscan2
- KCNB2 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 77/322 reads (24%) | catalogued as rs1359414670; called by muse, mutect2, varscan2
- KCNU1 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as rs763180709, COSV67757391; called by muse, mutect2
- KDM6B | c.1537del p.R513Afs*69 | Frame Shift Del (DEL) | VAF 16/88 reads (18%) | catalogued as rs747555402; called by mutect2, varscan2
- KIF26B | c.5725G>A p.G1909S | Missense Mutation (SNP) | VAF 57/270 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1432157761, COSV63640354; called by muse, mutect2, varscan2
- KIFC3 | c.2404C>T p.R802W | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1476210350, COSV65552914; called by muse, mutect2, varscan2
- KLC2 | c.572G>A p.G191D | Missense Mutation (SNP) | VAF 55/189 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.464); catalogued as rs1284019733; called by muse, mutect2, varscan2
- KLHL1 | c.104del p.G35Efs*31 | Frame Shift Del (DEL) | VAF 18/91 reads (20%) | catalogued as rs749011008; called by mutect2, pindel, varscan2
- LMO7 | c.2197C>T p.R733C (on ENST00000357063; = p.R414C on NM_005358.5) | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749357751, COSV58532445; called by muse, mutect2, varscan2
- LOXHD1 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs551430371; called by muse, mutect2, varscan2
- LRRC23 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 60/225 reads (27%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs781881095, COSV50391722; called by muse, mutect2, varscan2
- LRRC6 | c.1314_1315del p.P439Qfs*5 | Frame Shift Del (DEL) | VAF 31/168 reads (18%) | catalogued as rs1173280896; called by pindel, varscan2
- MAML1 | c.2897C>T p.A966V | Missense Mutation (SNP) | VAF 73/269 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as rs776719597; called by muse, mutect2, varscan2
- MAN1C1 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.613); catalogued as rs1412753671; called by muse, mutect2, varscan2
- MAN2B2 | c.232_234del p.E78del | In Frame Del (DEL) | VAF 45/275 reads (16%) | catalogued as rs1322865216; called by mutect2, pindel, varscan2
- MAP2K1 | c.1138G>A p.G380S | Missense Mutation (SNP) | VAF 97/394 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.062); catalogued as rs750934083; called by muse, mutect2, varscan2
- MARVELD3 | c.948del p.Y317Tfs*45 | Frame Shift Del (DEL) | VAF 69/288 reads (24%) | catalogued as rs747980715, COSV51704302; called by mutect2, pindel, varscan2
- MCM4 | c.371G>A p.G124D | Missense Mutation (SNP) | VAF 55/252 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.035); catalogued as rs1173474633, COSV50623288; called by muse, mutect2, varscan2
- MEIS2 | c.85G>A p.A29T (on ENST00000561208 / NM_170675.5; = p.A16T on NM_002399.3) | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.732); catalogued as COSV54942744; called by muse, mutect2, varscan2
- MIB1 | c.2410C>T p.R804W | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); catalogued as rs146823897; called by muse, mutect2, varscan2
- MICAL3 | c.4495del p.R1499Gfs*106 | Frame Shift Del (DEL) | VAF 52/202 reads (26%) | catalogued as rs765803753; called by mutect2, varscan2
- MMP8 | c.210T>G p.F70L | Missense Mutation (SNP) | VAF 109/483 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.405); catalogued as COSV52634246; called by muse, mutect2, varscan2
- MPV17L2 | c.493del p.Q165Nfs*10 | Frame Shift Del (DEL) | VAF 40/167 reads (24%) | catalogued as rs746591385; called by mutect2, varscan2
- MSGN1 | c.359G>A p.R120K | Missense Mutation (SNP) | VAF 75/342 reads (22%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as rs981143103, COSV55262966; called by muse, mutect2, varscan2
- MTO1 | c.1982G>A p.R661H (on ENST00000370300 / NM_133645.3; = p.R636H on NM_012123.4) | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs751695333, COSV64773281; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC2 | c.3352C>T p.P1118S | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as rs763395247; called by muse, mutect2, varscan2
- MYH6 | c.5696G>A p.R1899H | Missense Mutation (SNP) | VAF 123/500 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs61731171, COSV59305147; ClinVar: uncertain significance; called by muse, varscan2
- MYH8 | c.3389C>T p.A1130V | Missense Mutation (SNP) | VAF 93/366 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV101238063; called by muse, mutect2, varscan2
- NCEH1 | c.313dup p.S105Kfs*16 (on ENST00000538775; = p.S73Kfs*16 on NM_020792.6 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 86/435 reads (20%) | catalogued as rs759087510; called by mutect2, varscan2
- NOL9 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 47/192 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as rs371155768; called by muse, mutect2, varscan2
- NPHP1 | c.1331G>A p.R444H (on ENST00000393272 / NM_207181.4; = p.R445H on NM_000272.5) | Missense Mutation (SNP) | VAF 59/314 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as rs140979636, COSV57207165; called by muse, mutect2, varscan2
- NTF3 | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 58/260 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58417467; called by muse, mutect2, varscan2
- OCA2 | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 162/719 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as COSV62341550; called by muse, mutect2, varscan2
- OLIG3 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 102/425 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs1005109891; called by muse, mutect2, varscan2
- OTOF | c.2075G>A p.R692Q | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs147978393; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- P2RY8 | c.226T>A p.L76M | Missense Mutation (SNP) | VAF 60/270 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV67177594; called by muse, mutect2, varscan2
- PACS1 | c.2545C>A p.L849I | Missense Mutation (SNP) | VAF 14/370 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57698979; called by muse, mutect2
- PALD1 | c.2389C>T p.Q797* | Nonsense Mutation (SNP) | VAF 9/207 reads (4%) | catalogued as COSV99698801; called by muse, mutect2
- PANK1 | c.1199dup p.P401Afs*5 (on ENST00000307534 / NM_148977.2; = p.P176Afs*5 on NM_138316.4) | Frame Shift Ins (INS) | VAF 58/269 reads (22%) | catalogued as rs1564621823; called by mutect2, varscan2
- PAX1 | c.1145C>T p.P382L | Missense Mutation (SNP) | VAF 88/325 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.886); catalogued as rs541086527; called by muse, mutect2, varscan2
- PCDHB14 | c.1952C>T p.P651L | Missense Mutation (SNP) | VAF 49/248 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.169); catalogued as rs782498060, COSV99506367; called by muse, mutect2, varscan2
- PCDHB5 | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 19/84 reads (23%) | catalogued as rs1563869958, COSV50648997; called by muse, mutect2, varscan2
- PCDHGA2 | c.1627A>G p.S543G | Missense Mutation (SNP) | VAF 129/513 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.33); catalogued as COSV53936103; called by muse, mutect2, varscan2
- PDCD11 | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as rs146207561; called by muse, mutect2, varscan2
- PDCL3 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs752406527; called by muse, mutect2, varscan2
- PIEZO1 | c.4853G>A p.R1618H | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); catalogued as rs752059066, COSV56342930, COSV56343994, COSV99965433; called by muse, mutect2, varscan2
- PIGT | c.752C>T p.T251M | Missense Mutation (SNP) | VAF 67/292 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.024); catalogued as rs766494019, COSV54129240; called by muse, mutect2, varscan2
- PLCB2 | c.142T>C p.Y48H | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs148503632; called by muse, mutect2, varscan2
- PLCL1 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1157981086; called by muse, mutect2, varscan2
- PLEK | c.464G>A p.C155Y | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52252754; called by muse, mutect2, varscan2
- PNISR | c.1491del p.E498Sfs*85 | Frame Shift Del (DEL) | VAF 29/125 reads (23%) | catalogued as rs1401239378; called by mutect2, pindel, varscan2
- PORCN | c.443C>T p.T148M | Missense Mutation (SNP) | VAF 86/378 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs782273836, COSV58226682; called by muse, mutect2, varscan2
- PPP1R8 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1397039365; called by muse, mutect2, varscan2
- PPP2CB | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 24/153 reads (16%) | catalogued as COSV55328872; called by muse, mutect2, varscan2
- PRPF8 | c.4774G>T p.D1592Y | Missense Mutation (SNP) | VAF 98/446 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59260109, COSV59267815; called by muse, mutect2, varscan2
- PRR33 | c.146_148del p.K49del | In Frame Del (DEL) | VAF 70/336 reads (21%) | catalogued as rs1315204675; called by pindel, varscan2
- PRSS16 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1304360976; called by muse, mutect2, varscan2
- PTPRU | c.1238G>A p.R413H | Missense Mutation (SNP) | VAF 108/476 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs775138343, COSV60536048; called by muse, mutect2, varscan2
- QRFPR | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 67/241 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.023); catalogued as COSV57675692; called by muse, mutect2, varscan2
- RALGAPA2 | c.1091G>A p.S364N | Missense Mutation (SNP) | VAF 97/496 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs556194705; called by muse, mutect2, varscan2
- RANBP3 | c.1574C>T p.A525V (on ENST00000340578 / NM_007322.3; = p.A520V on NM_003624.3) | Missense Mutation (SNP) | VAF 52/231 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.089); catalogued as rs1381673349, COSV50380259; called by muse, mutect2, varscan2
- RAX | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 19/441 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); catalogued as rs985273475; called by muse, mutect2
- RBM6 | c.2502del p.K834Nfs*27 | Frame Shift Del (DEL) | VAF 21/138 reads (15%) | catalogued as COSV56484832; called by mutect2, varscan2
- REL | c.1665del p.F555Lfs*20 | Frame Shift Del (DEL) | VAF 35/136 reads (26%) | catalogued as COSV54362500; called by mutect2, pindel, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 16/76 reads (21%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RNF166 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 53/194 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs750497512, COSV57189881; called by muse, mutect2, varscan2
- RPN1 | c.1286C>T p.T429M | Missense Mutation (SNP) | VAF 54/234 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs770055133, COSV56189368; called by muse, mutect2, varscan2
- RYR1 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 140/602 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757399861, COSV62100636, COSV62112455; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR3 | c.4708G>A p.A1570T | Missense Mutation (SNP) | VAF 56/228 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs774393965, COSV66804560; called by muse, mutect2, varscan2
- SAGE1 | c.1946C>A p.P649H | Missense Mutation (SNP) | VAF 35/194 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61017799; called by muse, mutect2, varscan2
- SEC23IP | c.2851G>A p.V951I | Missense Mutation (SNP) | VAF 50/246 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756330451, COSV100956869; called by muse, mutect2, varscan2
- SEMA3B | c.2171G>A p.R724Q | Missense Mutation (SNP) | VAF 66/262 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0.155); catalogued as rs368594845; called by muse, mutect2, varscan2
- SENP1 | c.1227del p.G410Vfs*4 | Frame Shift Del (DEL) | VAF 31/94 reads (33%) | catalogued as rs750651342; called by mutect2, varscan2
- SETD1B | c.3932C>T p.P1311L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.093); catalogued as rs554437974; called by muse, mutect2
- SETDB1 | c.1189C>T p.P397S | Missense Mutation (SNP) | VAF 64/299 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1406095791, COSV99643438; called by muse, mutect2, varscan2
- SGIP1 | c.1529C>T p.S510L | Missense Mutation (SNP) | VAF 55/263 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs748359882, COSV52774055; called by muse, mutect2, varscan2
- SHANK1 | c.5003C>T p.P1668L | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.716); catalogued as rs761162869, COSV53250387; called by muse, mutect2, varscan2
- SHC2 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs566605373; called by muse, mutect2, varscan2
- SLC3A2 | c.1807C>T p.R603C | Missense Mutation (SNP) | VAF 53/271 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.759); catalogued as rs752860221, COSV58603040; called by muse, mutect2, varscan2
- SLC45A1 | c.1109C>T p.T370M | Missense Mutation (SNP) | VAF 98/436 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs377250283; called by muse, mutect2, varscan2
- SLC4A11 | c.1483G>A p.A495T | Missense Mutation (SNP) | VAF 119/577 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1348429438, COSV66260706; called by muse, mutect2, varscan2
- SLC6A11 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs746655671, COSV54394336; called by muse, mutect2, varscan2
- SMC5 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs750803383; called by muse, mutect2, varscan2
- SPAG17 | c.2855G>A p.R952H | Missense Mutation (SNP) | VAF 59/193 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200995274, COSV60455007; called by muse, mutect2, varscan2
- SPANXN3 | c.71del p.N24Mfs*12 | Frame Shift Del (DEL) | VAF 22/116 reads (19%) | catalogued as rs781940283; called by mutect2, varscan2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 26/106 reads (25%) | catalogued as COSV54965656; called by mutect2, varscan2
- SPHKAP | c.2131C>A p.Q711K | Missense Mutation (SNP) | VAF 50/209 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV60891092; called by muse, mutect2, varscan2
- SPSB2 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 84/388 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs781906850, COSV51290168; called by muse, mutect2, varscan2
- SPTLC3 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); catalogued as COSV65466269; called by muse, mutect2, varscan2
- SRGAP1 | c.2600G>A p.G867D | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as rs776550286; called by muse, mutect2, varscan2
- SRGAP3 | c.2281C>T p.R761C | Missense Mutation (SNP) | VAF 88/393 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1033693138, COSV64532959; called by muse, mutect2, varscan2
- STK32B | c.824A>G p.H275R | Missense Mutation (SNP) | VAF 68/338 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1408968323, COSV99286876; called by muse, mutect2, varscan2
- TDRD3 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.398); catalogued as rs758407063, COSV52165051, COSV99540204; called by muse, mutect2, varscan2
- TENM4 | c.8293G>A p.E2765K | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.981); catalogued as rs376914004; called by muse, mutect2, varscan2
- TEX2 | c.2366G>A p.R789Q (on ENST00000583097 / NM_001288733.2; = p.R796Q on NM_018469.5) | Missense Mutation (SNP) | VAF 57/222 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs377267817; called by muse, mutect2, varscan2
- TMCO4 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs1036421756; called by muse, mutect2, varscan2
- TMEM52 | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 58/244 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.736); catalogued as rs566773598, COSV57069590; called by muse, mutect2, varscan2
- TMEM68 | c.890C>T p.T297M (on ENST00000434581 / NM_001363177.1; = p.T230M on NM_152417.3) | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV100588353; called by muse, mutect2, varscan2
- TNKS1BP1 | c.2635C>T p.R879* | Nonsense Mutation (SNP) | VAF 82/407 reads (20%) | catalogued as rs779725739, COSV64102384; called by muse, mutect2, varscan2
- TRAPPC9 | c.2657C>T p.P886L | Missense Mutation (SNP) | VAF 27/560 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as rs752774559; called by muse, mutect2
- TSPYL2 | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1556808032; called by muse, mutect2, varscan2
- TTBK1 | c.3766C>T p.R1256C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as COSV52491308; called by muse, mutect2, varscan2
- TTK | c.2571del p.K857Nfs*36 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | catalogued as rs768996038, COSV57882295; called by mutect2, varscan2
- TTLL3 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs752644960; called by muse, mutect2, varscan2
- UBE2S | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 22/473 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.974); catalogued as rs1235935851, COSV99198757; called by muse, mutect2
- UBR4 | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 50/287 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.959); catalogued as rs776684278, COSV100920318; called by muse, mutect2, varscan2
- UBR5 | c.6568C>T p.R2190C | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as COSV55282258; called by muse, mutect2, varscan2
- USP40 | c.3441del p.K1147Nfs*12 | Frame Shift Del (DEL) | VAF 59/273 reads (22%) | catalogued as rs572063854; called by mutect2, varscan2
- USP42 | c.3875G>A p.R1292H | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as rs371531352; called by muse, mutect2, varscan2
- VPS18 | c.1759G>A p.A587T | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs777380939, COSV55030971; called by muse, mutect2, varscan2
- VWA3B | c.2759G>A p.R920Q | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs367940324; called by muse, mutect2, varscan2
- XPNPEP1 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 95/352 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs777814357; called by muse, mutect2, varscan2
- YTHDF2 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 43/282 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1376549189; called by muse, mutect2, varscan2
- ZBTB7A | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.213); catalogued as rs1290377548; called by muse, mutect2, varscan2
- ZBTB9 | c.1125del p.T376Hfs*19 | Frame Shift Del (DEL) | VAF 29/114 reads (25%) | catalogued as COSV101221723; called by mutect2, pindel, varscan2
- ZFHX4 | c.7228G>A p.A2410T | Missense Mutation (SNP) | VAF 52/215 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs770276733, COSV50588067; called by muse, mutect2, varscan2
- ZNF347 | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 9/236 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1326879506; called by muse, mutect2
- ZNF407 | c.6043G>A p.G2015S | Missense Mutation (SNP) | VAF 49/233 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as rs748221235, COSV55268799; called by muse, mutect2, varscan2
- ZNF488 | c.308C>T p.T103M | Missense Mutation (SNP) | VAF 67/308 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as rs782681733; called by muse, mutect2, varscan2
- ZNF518A | c.2785del p.T929Lfs*2 | Frame Shift Del (DEL) | VAF 68/144 reads (47%) | catalogued as rs781933025; called by mutect2, varscan2
- ZNF592 | c.662G>A p.S221N | Missense Mutation (SNP) | VAF 85/356 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.019); catalogued as rs1354015786; called by muse, mutect2, varscan2
- ZNF862 | c.811del p.D271Mfs*9 | Frame Shift Del (DEL) | VAF 42/182 reads (23%) | catalogued as rs769847259; called by mutect2, varscan2
- ZSCAN4 | c.1274G>A p.S425N | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs372874180; called by muse, mutect2, varscan2
- ACAD11 | c.1608del p.K536Nfs*34 | Frame Shift Del (DEL) | VAF 39/173 reads (23%) | called by mutect2, pindel, varscan2
- ADAMTS10 | c.435G>A p.L145= | Splice Region (SNP) | VAF 43/254 reads (17%) | called by muse, mutect2, varscan2
- ADCY2 | c.83G>A p.R28Q | Missense Mutation (SNP) | VAF 58/244 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ADD1 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.78); called by muse, mutect2
- ADGRV1 | c.6046G>A p.A2016T | Missense Mutation (SNP) | VAF 95/438 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ADGRV1 | c.17450del p.N5817Ifs*6 | Frame Shift Del (DEL) | VAF 23/121 reads (19%) | called by mutect2, pindel, varscan2
- ADSL | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 78/357 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- AL136295.1 | c.830G>T p.C277F | Missense Mutation (SNP) | VAF 83/353 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- AR | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 86/330 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ARID5B | c.1489dup p.I497Nfs*31 | Frame Shift Ins (INS) | VAF 34/132 reads (26%) | called by mutect2, varscan2
- ARSL | c.812C>T p.T271M | Missense Mutation (SNP) | VAF 19/297 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.117); called by muse, mutect2
- ARX | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATP6V1B1 | c.1537C>T p.L513F | Missense Mutation (SNP) | VAF 101/435 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRMS1 | c.95A>G p.E32G | Missense Mutation (SNP) | VAF 53/262 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- BTNL3 | c.1058G>A p.W353* | Nonsense Mutation (SNP) | VAF 57/215 reads (27%) | called by muse, mutect2, varscan2
- C2orf42 | c.510G>T p.W170C | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C2orf72 | c.86del p.G29Afs*197 | Frame Shift Del (DEL) | VAF 14/88 reads (16%) | called by mutect2, pindel, varscan2
- CAMTA1 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 54/227 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- CASP8AP2 | c.761A>G p.Q254R | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- CCNO | c.793del p.V265Wfs*4 | Frame Shift Del (DEL) | VAF 72/344 reads (21%) | called by mutect2, varscan2
- CCSER2 | c.659G>T p.R220M | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDC42BPB | c.3867_3868dup p.E1290Gfs*5 | Frame Shift Ins (INS) | VAF 37/176 reads (21%) | called by mutect2, pindel, varscan2
- CDK13 | c.3128C>A p.P1043H | Missense Mutation (SNP) | VAF 43/237 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- CDKL1 | c.722T>A p.I241N | Missense Mutation (SNP) | VAF 46/197 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, varscan2
- CEP83 | c.1344-3del | Splice Region (DEL) | VAF 40/198 reads (20%) | called by mutect2, pindel, varscan2
- CERK | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CES2 | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- COPA | c.512del p.N171Tfs*11 | Frame Shift Del (DEL) | VAF 39/223 reads (17%) | called by mutect2, varscan2
- CSMD1 | c.6733G>T p.G2245C (on ENST00000520002; = p.G2244C on NM_033225.6) | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSPG4 | c.4992del p.E1665Sfs*10 | Frame Shift Del (DEL) | VAF 38/183 reads (21%) | called by mutect2, pindel, varscan2
- CXXC1 | c.1820G>A p.R607H | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- CYLD | c.2807G>A p.R936Q | Missense Mutation (SNP) | VAF 58/226 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CYP4F8 | c.1292C>A p.P431H | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- DDX50 | c.943+1del | Frame Shift Del (DEL) | VAF 25/82 reads (30%) | called by mutect2, pindel, varscan2
- DNAH1 | c.11684T>C p.M3895T | Missense Mutation (SNP) | VAF 68/295 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- DNAH11 | c.10265G>T p.G3422V | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH9 | c.5418G>A p.W1806* | Nonsense Mutation (SNP) | VAF 41/129 reads (32%) | called by muse, mutect2, varscan2
- DOCK4 | c.869del p.K290Rfs*23 | Frame Shift Del (DEL) | VAF 54/265 reads (20%) | called by mutect2, pindel, varscan2
- DOP1A | c.5630C>T p.T1877I | Missense Mutation (SNP) | VAF 27/144 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DPYS | c.1445C>G p.T482S | Missense Mutation (SNP) | VAF 34/373 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2
- DRD1 | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 10/261 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DTNA | c.1787G>T p.G596V | Missense Mutation (SNP) | VAF 107/416 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- DTX1 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- EFEMP2 | c.847+7G>A | Splice Region (SNP) | VAF 123/508 reads (24%) | called by muse, mutect2, varscan2
- ELAPOR2 | c.2755G>A p.A919T (on ENST00000450689 / NM_001142749.3; = p.A752T on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- ELK1 | c.65A>G p.H22R | Missense Mutation (SNP) | VAF 66/314 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ENHO | c.7del p.A3Qfs*86 | Frame Shift Del (DEL) | VAF 29/135 reads (21%) | called by mutect2, pindel, varscan2
- ERGIC2 | c.911T>C p.V304A | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- EXPH5 | c.3949T>C p.S1317P | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EYA4 | c.1856dup p.H620Afs*48 (on ENST00000531901 / NM_001301013.1; = p.H614Afs*48 on NM_004100.5) | Frame Shift Ins (INS) | VAF 91/491 reads (19%) | called by mutect2, pindel, varscan2
- FAM133A | c.157del p.T53Qfs*6 | Frame Shift Del (DEL) | VAF 25/145 reads (17%) | called by mutect2, pindel, varscan2
- FCSK | c.235-4G>A | Splice Region (SNP) | VAF 43/174 reads (25%) | called by muse, mutect2, varscan2
- FER | c.1428del p.K476Nfs*53 | Frame Shift Del (DEL) | VAF 36/206 reads (17%) | called by mutect2, pindel, varscan2
- FGD4 | c.940A>T p.K314* | Nonsense Mutation (SNP) | VAF 41/178 reads (23%) | called by muse, mutect2, varscan2
- FGD5 | c.1160A>G p.N387S | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FLT4 | c.3335C>A p.A1112D | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FMNL2 | c.1412del p.K471Rfs*5 | Frame Shift Del (DEL) | VAF 20/117 reads (17%) | called by mutect2, pindel, varscan2
- FUBP3 | c.1184del p.P395Lfs*27 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | called by mutect2, pindel, varscan2
- FXYD1 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 46/225 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GDF10 | c.700del p.V234Cfs*12 | Frame Shift Del (DEL) | VAF 74/270 reads (27%) | called by mutect2, varscan2
- GDF6 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 56/255 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- GGCT | c.393A>T p.E131D | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.012); called by muse, mutect2
- GGTLC2 | c.142_144dup p.S48dup | In Frame Ins (INS) | VAF 60/262 reads (23%) | called by mutect2, pindel, varscan2
- GIMAP2 | c.361C>T p.Q121* | Nonsense Mutation (SNP) | VAF 81/282 reads (29%) | called by muse, mutect2, varscan2
- GIT1 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- GLB1 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 101/429 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- GNAI3 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 39/228 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HCN2 | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HIGD1C | c.173A>G p.H58R | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.361); called by muse, mutect2
- HOMEZ | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HRC | c.308T>C p.L103P | Missense Mutation (SNP) | VAF 49/233 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- HRH3 | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HSPA6 | c.29G>A p.G10D | Missense Mutation (SNP) | VAF 53/333 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IDH3G | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 57/223 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KANSL1 | c.1867A>T p.I623F | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- KAT2B | c.1277-1G>T p.X426_splice | Splice Site (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- KCND2 | c.1132C>A p.P378T | Missense Mutation (SNP) | VAF 59/299 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KCNG2 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF19 | c.2264del p.P755Lfs*21 | Frame Shift Del (DEL) | VAF 87/396 reads (22%) | called by mutect2, pindel, varscan2
- KIZ | c.134A>T p.N45I | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- KLF10 | c.997G>T p.V333L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KRT19 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 114/470 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- LARS2 | c.*14C>T | Splice Region (SNP) | VAF 40/218 reads (18%) | called by muse, mutect2, varscan2
- LILRB1 | c.1897T>C p.S633P (on ENST00000427581; = p.S582P on NM_006669.6) | Missense Mutation (SNP) | VAF 86/358 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, varscan2
- LLGL2 | c.3032G>T p.G1011V (on ENST00000392550 / NM_001031803.2; = p.G997C on NM_004524.3) | Missense Mutation (SNP) | VAF 60/266 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- LONP1 | c.1029_1030del p.H344* | Frame Shift Del (DEL) | VAF 36/180 reads (20%) | called by mutect2, pindel, varscan2
- LPAR1 | c.638del p.F213Sfs*4 | Frame Shift Del (DEL) | VAF 54/248 reads (22%) | called by mutect2, pindel, varscan2
- LRFN1 | c.2218G>T p.G740W | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- LRP1 | c.3954G>T p.E1318D | Missense Mutation (SNP) | VAF 65/306 reads (21%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- LRRC73 | c.31dup p.E11Gfs*54 | Frame Shift Ins (INS) | VAF 21/130 reads (16%) | called by mutect2, pindel, varscan2
- MAP3K1 | c.948_949del p.Y317Lfs*8 | Frame Shift Del (DEL) | VAF 120/539 reads (22%) | called by mutect2, pindel, varscan2
- MED27 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MGAT5 | c.1349T>C p.L450P | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MMS19 | c.1720C>T p.P574S | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MRI1 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MRNIP | c.421del p.R141Afs*44 | Frame Shift Del (DEL) | VAF 31/151 reads (21%) | called by mutect2, pindel, varscan2
- MROH1 | c.3858G>A p.M1286I | Missense Mutation (SNP) | VAF 90/339 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MRPL1 | c.751A>T p.N251Y | Missense Mutation (SNP) | VAF 39/219 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- MS4A14 | c.96C>A p.S32R | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- MSH2 | c.418_420del p.D140del | In Frame Del (DEL) | VAF 44/203 reads (22%) | called by mutect2, pindel, varscan2
- MUC22 | c.1283C>A p.T428K | Missense Mutation (SNP) | VAF 50/250 reads (20%) | SIFT deleterious (0.03); called by muse, mutect2, varscan2
- MYCBP2 | c.13613G>A p.G4538D (on ENST00000357337; = p.G4576D on NM_015057.5) | Missense Mutation (SNP) | VAF 42/223 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NAIP | c.409A>G p.K137E | Missense Mutation (SNP) | VAF 59/233 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NBEA | c.289A>G p.N97D | Missense Mutation (SNP) | VAF 45/187 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- NELL2 | c.316A>T p.I106F | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- NEURL1 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- NKAIN2 | c.106C>A p.P36T | Missense Mutation (SNP) | VAF 42/214 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NOTO | c.436dup p.T146Nfs*8 | Frame Shift Ins (INS) | VAF 55/311 reads (18%) | called by mutect2, pindel, varscan2
- NUAK1 | c.707G>A p.S236N | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ODF3L2 | c.653del p.R218Pfs*33 | Frame Shift Del (DEL) | VAF 44/278 reads (16%) | called by mutect2, pindel, varscan2
- OGDH | c.2661A>C p.E887D | Missense Mutation (SNP) | VAF 10/219 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.005); called by muse, mutect2
- OR11A1 | c.562C>A p.L188M | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR4S2 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OSBPL7 | c.652_655dup p.E219Afs*44 | Frame Shift Ins (INS) | VAF 22/121 reads (18%) | called by mutect2, pindel, varscan2
- OTUD7A | c.2530G>A p.A844T (on ENST00000307050 / NM_001382637.1; = p.A837T on NM_130901.3) | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- OXNAD1 | c.619A>T p.I207L | Missense Mutation (SNP) | VAF 49/244 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAM | c.2375C>G p.T792S | Missense Mutation (SNP) | VAF 28/204 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- PAWR | c.967C>T p.Q323* | Nonsense Mutation (SNP) | VAF 33/178 reads (19%) | called by muse, mutect2, varscan2
- PDE5A | c.1849C>T p.H617Y | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDS5A | c.3352G>T p.D1118Y | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- PDZD2 | c.4949C>T p.A1650V | Missense Mutation (SNP) | VAF 36/184 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PGR | c.1735_1737del p.Y579del | In Frame Del (DEL) | VAF 65/304 reads (21%) | called by mutect2, pindel, varscan2
- PIKFYVE | c.6260T>A p.V2087E | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PLA2G3 | c.125del p.L42Rfs*4 | Frame Shift Del (DEL) | VAF 59/275 reads (21%) | called by mutect2, pindel, varscan2
- PLPBP | c.316A>T p.M106L | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLXND1 | c.2022del p.N675Tfs*5 | Frame Shift Del (DEL) | VAF 18/96 reads (19%) | called by mutect2, pindel, varscan2
- POLA1 | c.3451dup p.S1151Kfs*46 | Frame Shift Ins (INS) | VAF 33/151 reads (22%) | called by mutect2, varscan2
- PPFIA2 | c.2714C>T p.A905V | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PPP2R5D | c.1012G>A p.V338I | Missense Mutation (SNP) | VAF 52/263 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- PRDM7 | c.592C>T p.Q198* | Nonsense Mutation (SNP) | VAF 57/298 reads (19%) | called by muse, mutect2, varscan2
- PRKDC | c.4958dup p.L1653Ffs*4 | Frame Shift Ins (INS) | VAF 15/57 reads (26%) | called by mutect2, pindel, varscan2
- PRR15 | c.196G>T p.G66W | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- PTCD1 | c.126G>A p.M42I | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRU | c.2283_2285del p.L763del | In Frame Del (DEL) | VAF 16/122 reads (13%) | called by mutect2, pindel
- PZP | c.1775C>T p.A592V | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RAD21L1 | c.86A>T p.K29M | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAD50 | c.2864A>G p.H955R | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- RASAL2 | c.1958C>T p.P653L | Missense Mutation (SNP) | VAF 40/227 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.065); called by muse, mutect2
- REST | c.1300G>T p.E434* | Nonsense Mutation (SNP) | VAF 10/231 reads (4%) | called by muse, mutect2
- RIBC2 | c.192del p.A65Lfs*10 | Frame Shift Del (DEL) | VAF 22/113 reads (19%) | called by mutect2, pindel, varscan2
- RNF31 | c.1204del p.D402Mfs*90 | Frame Shift Del (DEL) | VAF 18/67 reads (27%) | called by mutect2, pindel, varscan2
- ROGDI | c.629A>G p.Q210R | Missense Mutation (SNP) | VAF 61/278 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- RSAD1 | c.1019C>A p.T340N | Missense Mutation (SNP) | VAF 52/231 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- RUBCNL | c.887A>G p.E296G | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- SAMD10 | c.271del p.Q91Rfs*21 | Frame Shift Del (DEL) | VAF 37/216 reads (17%) | called by mutect2, pindel, varscan2
- SCO2 | c.164C>A p.P55H | Missense Mutation (SNP) | VAF 107/396 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- SETD1B | c.22del p.H8Tfs*27 | Frame Shift Del (DEL) | VAF 21/72 reads (29%) | called by mutect2, varscan2
- SLC30A7 | c.363del p.F121Lfs*11 | Frame Shift Del (DEL) | VAF 36/190 reads (19%) | called by mutect2, varscan2
- SLC6A8 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SLC8A2 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 64/231 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC9A3 | c.154G>A p.V52M | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLCO3A1 | c.1292C>A p.S431Y | Missense Mutation (SNP) | VAF 54/351 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SLCO3A1 | c.1936C>T p.Q646* | Nonsense Mutation (SNP) | VAF 52/202 reads (26%) | called by muse, mutect2, varscan2
- SOX3 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- SPZ1 | c.982T>C p.C328R | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- STAB1 | c.307G>T p.G103C | Missense Mutation (SNP) | VAF 72/315 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STARD9 | c.1192C>A p.L398M | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- STEAP2 | c.932dup p.F312Lfs*35 | Frame Shift Ins (INS) | VAF 12/69 reads (17%) | called by mutect2, pindel, varscan2
- STYK1 | c.1089G>A p.W363* | Nonsense Mutation (SNP) | VAF 61/240 reads (25%) | called by muse, mutect2, varscan2
- SYNJ1 | c.2438del p.L813* | Frame Shift Del (DEL) | VAF 16/112 reads (14%) | called by mutect2, pindel
- TAOK1 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- TBC1D32 | c.917G>A p.W306* | Nonsense Mutation (SNP) | VAF 20/96 reads (21%) | called by muse, mutect2, varscan2
- TBXAS1 | c.236G>T p.G79V | Missense Mutation (SNP) | VAF 59/306 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TF | c.978del p.R327Gfs*35 | Frame Shift Del (DEL) | VAF 24/136 reads (18%) | called by mutect2, varscan2
- THYN1 | c.581del p.N194Ifs*15 | Frame Shift Del (DEL) | VAF 41/215 reads (19%) | called by mutect2, pindel, varscan2
- TJP2 | c.446G>A p.R149K | Missense Mutation (SNP) | VAF 112/492 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMEM129 | c.883G>T p.V295L | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- TMEM230 | c.-16+8G>A | Splice Region (SNP) | VAF 123/516 reads (24%) | called by muse, mutect2, varscan2
- TMEM9B | c.513G>T p.K171N | Missense Mutation (SNP) | VAF 49/262 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- TNKS2 | c.3462_3465del p.Y1155Rfs*3 | Frame Shift Del (DEL) | VAF 20/156 reads (13%) | called by pindel, varscan2
- TRIL | c.1181del p.P394Rfs*30 | Frame Shift Del (DEL) | VAF 14/99 reads (14%) | called by mutect2, pindel, varscan2
- TRNT1 | c.227A>G p.Q76R | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- TWIST2 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 14/284 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- UBC | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 110/546 reads (20%) | called by muse, mutect2, varscan2
- USH2A | c.1049T>C p.V350A | Missense Mutation (SNP) | VAF 50/261 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- VCAN | c.6412_6415del p.T2138Sfs*20 | Frame Shift Del (DEL) | VAF 37/184 reads (20%) | called by pindel, varscan2
- VIL1 | c.1193G>T p.G398V | Missense Mutation (SNP) | VAF 65/244 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VPS37B | c.348G>T p.K116N | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDR33 | c.219_220del p.D75Pfs*10 | Frame Shift Del (DEL) | VAF 45/203 reads (22%) | called by mutect2, pindel, varscan2
- XIRP2 | c.165A>T p.Q55H | Missense Mutation (SNP) | VAF 66/279 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF324 | c.543G>T p.E181D | Missense Mutation (SNP) | VAF 64/282 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF469 | c.1963del p.H655Tfs*77 | Frame Shift Del (DEL) | VAF 58/284 reads (20%) | called by mutect2, varscan2
- ZNF740 | c.225_226del p.H76Ffs*6 | Frame Shift Del (DEL) | VAF 38/219 reads (17%) | called by pindel, varscan2
- ABCB9 | c.693C>T p.I231= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as rs760193984, COSV54894020; called by muse, mutect2, varscan2
- ABCG5 | c.1950C>T p.S650= | Silent (SNP) | VAF 72/329 reads (22%) | catalogued as rs1184078765; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABI3 | c.504A>G p.R168= | Silent (SNP) | VAF 22/115 reads (19%) | called by muse, mutect2, varscan2
- ACAT2 | c.240C>G p.P80= | Silent (SNP) | VAF 47/227 reads (21%) | called by muse, mutect2, varscan2
- ADAR | c.2907C>T p.G969= | Silent (SNP) | VAF 76/332 reads (23%) | catalogued as rs185906367, COSV52717873; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGGF1 | c.861T>C p.N287= | Silent (SNP) | VAF 32/132 reads (24%) | called by muse, mutect2, varscan2
- ANHX | c.609G>A p.Q203= | Silent (SNP) | VAF 32/172 reads (19%) | called by muse, mutect2, varscan2
- ANKZF1 | c.711G>A p.T237= | Silent (SNP) | VAF 78/405 reads (19%) | catalogued as rs775987387; called by muse, mutect2, varscan2
- ARRB2 | c.189C>T p.R63= | Silent (SNP) | VAF 100/431 reads (23%) | called by muse, mutect2, varscan2
- ARV1 | c.706T>C p.L236= | Silent (SNP) | VAF 49/171 reads (29%) | called by muse, mutect2, varscan2
- ASB10 | c.454C>T p.L152= (on ENST00000420175 / NM_001142459.2; = p.L137= on NM_080871.4) | Silent (SNP) | VAF 94/391 reads (24%) | called by muse, mutect2, varscan2
- ASB14 | c.627C>T p.H209= (on ENST00000389601; = p.H208= on NM_001142733.3) | Silent (SNP) | VAF 16/533 reads (3%) | called by muse, mutect2
- ATP11A | c.2925C>T p.D975= | Silent (SNP) | VAF 66/333 reads (20%) | catalogued as rs151314075; called by muse, mutect2, varscan2
- B3GNT9 | c.237G>A p.T79= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as rs753625892; called by muse, mutect2, varscan2
- B4GALNT4 | c.2706C>T p.D902= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs777258020; called by muse, mutect2, varscan2
- BCAR1 | c.1953G>A p.G651= | Silent (SNP) | VAF 14/58 reads (24%) | called by muse, mutect2, varscan2
- CANT1 | c.846C>A p.I282= | Silent (SNP) | VAF 9/184 reads (5%) | called by muse, mutect2
- CASKIN1 | c.3195G>A p.T1065= | Silent (SNP) | VAF 56/302 reads (19%) | catalogued as rs777290410, COSV58217305; called by muse, mutect2, varscan2
- CDC42BPB | c.357G>A p.A119= | Silent (SNP) | VAF 48/174 reads (28%) | catalogued as rs375791786; called by muse, mutect2, varscan2
- CFAP94 | c.1944C>T p.D648= (on ENST00000320267 / NM_001352064.2; = p.D654= on NM_018272.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 47/208 reads (23%) | catalogued as rs1401422688; called by muse, mutect2, varscan2
- CHD3 | c.1395C>T p.G465= | Silent (SNP) | VAF 74/305 reads (24%) | catalogued as rs759896915, COSV100390633; called by muse, mutect2, varscan2
- CHRNA7 | c.1179C>T p.D393= | Silent (SNP) | VAF 32/226 reads (14%) | catalogued as rs752171678; called by mutect2, varscan2
- COL18A1 | c.4944G>A p.E1648= (on ENST00000359759 / NM_130444.3; = p.E1413= on NM_030582.4) | Silent (SNP) | VAF 128/543 reads (24%) | catalogued as rs1447453546; called by muse, mutect2, varscan2
- COL4A2 | c.3057G>T p.L1019= | Silent (SNP) | VAF 35/142 reads (25%) | called by muse, mutect2, varscan2
- CRIM1 | c.1128C>T p.C376= | Silent (SNP) | VAF 29/132 reads (22%) | catalogued as rs777725191, COSV54868129, COSV54870759; called by muse, mutect2, varscan2
- CT47B1 | c.585G>T p.S195= | Silent (SNP) | VAF 130/631 reads (21%) | catalogued as COSV100988866, COSV64891633; called by muse, varscan2
- CUL9 | c.3735C>T p.I1245= | Silent (SNP) | VAF 54/240 reads (23%) | catalogued as rs373927467; called by muse, mutect2, varscan2
- DNAH2 | c.6162C>T p.D2054= | Silent (SNP) | VAF 57/247 reads (23%) | called by muse, mutect2, varscan2
- DOCK11 | c.537T>C p.S179= | Silent (SNP) | VAF 20/126 reads (16%) | called by muse, mutect2, varscan2
- DOCK9 | c.5625C>T p.D1875= (on ENST00000376460 / NM_001366676.2; = p.D1876= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/510 reads (10%) | catalogued as rs747381510, COSV59630991; called by muse, mutect2
- EDNRB | c.459G>A p.A153= (on ENST00000377211 / NM_001201397.1; = p.A63= on NM_000115.5) | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as COSV57518710; called by muse, mutect2, varscan2
- EDRF1 | c.2691C>A p.T897= (on ENST00000356792 / NM_001202438.2; = p.T863= on NM_015608.2) | Silent (SNP) | VAF 107/511 reads (21%) | called by muse, mutect2, varscan2
- EIF3A | c.601T>C p.L201= | Silent (SNP) | VAF 57/261 reads (22%) | called by muse, mutect2, varscan2
- EPB41L4A | c.1239G>A p.P413= | Silent (SNP) | VAF 49/231 reads (21%) | catalogued as rs770394354, COSV54866446; called by muse, mutect2, varscan2
- EPHB4 | c.1962G>A p.T654= | Silent (SNP) | VAF 59/269 reads (22%) | catalogued as rs918807315; called by muse, mutect2, varscan2
- EYS | c.3664T>C p.L1222= | Silent (SNP) | VAF 8/240 reads (3%) | called by muse, mutect2
- F5 | c.5406C>T p.S1802= | Silent (SNP) | VAF 57/304 reads (19%) | called by muse, mutect2, varscan2
- FAHD2B | c.633C>T p.F211= | Silent (SNP) | VAF 52/292 reads (18%) | catalogued as rs1361710949; called by muse, mutect2, varscan2
- FOXE1 | c.384G>A p.A128= | Silent (SNP) | VAF 59/237 reads (25%) | catalogued as COSV64301149; called by muse, mutect2, varscan2
- FOXG1 | c.1185C>A p.P395= | Silent (SNP) | VAF 22/763 reads (3%) | called by muse, mutect2
- FREM1 | c.6264C>A p.G2088= | Silent (SNP) | VAF 26/179 reads (15%) | called by muse, mutect2, varscan2
- GJB3 | c.768C>T p.G256= | Silent (SNP) | VAF 12/357 reads (3%) | catalogued as COSV64904496; called by muse, mutect2
- GLI2 | c.3213G>A p.T1071= (on ENST00000361492 / NM_001374353.1; = p.T1088= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 133/484 reads (27%) | catalogued as rs775682488; called by muse, mutect2, varscan2
- GMFB | c.231T>C p.H77= | Silent (SNP) | VAF 18/111 reads (16%) | catalogued as rs761700818; called by muse, mutect2, varscan2
- GP6 | c.279A>C p.G93= | Silent (SNP) | VAF 100/486 reads (21%) | called by muse, mutect2, varscan2
- GRIA1 | c.540C>T p.T180= | Silent (SNP) | VAF 43/222 reads (19%) | called by muse, mutect2
- GRIN2B | c.2298C>A p.I766= | Silent (SNP) | VAF 41/159 reads (26%) | called by muse, mutect2, varscan2
- GYPA | c.336C>T p.Y112= | Silent (SNP) | VAF 52/337 reads (15%) | catalogued as rs140442202; called by muse, mutect2, varscan2
- HLX | c.858G>A p.L286= | Silent (SNP) | VAF 17/262 reads (6%) | called by muse, mutect2
- HMCN1 | c.15765T>C p.I5255= | Silent (SNP) | VAF 53/208 reads (25%) | called by muse, mutect2, varscan2
- HSPA12A | c.1953C>T p.T651= | Silent (SNP) | VAF 80/308 reads (26%) | catalogued as rs782209908, COSV65022809; called by muse, mutect2, varscan2
- HYDIN | c.6579T>C p.S2193= | Silent (SNP) | VAF 38/188 reads (20%) | called by muse, mutect2, varscan2
- IQSEC2 | c.3444T>C p.S1148= (on ENST00000642864 / NM_001111125.3; = p.S943= on NM_015075.2) | Silent (SNP) | VAF 78/313 reads (25%) | called by muse, mutect2, varscan2
- IRF2BP1 | c.1527G>A p.R509= | Silent (SNP) | VAF 34/148 reads (23%) | catalogued as rs1239484335; called by muse, mutect2, varscan2
- ITPRIP | c.1080C>T p.Y360= | Silent (SNP) | VAF 44/228 reads (19%) | called by muse, mutect2, varscan2
- JPH1 | c.726C>T p.D242= | Silent (SNP) | VAF 99/451 reads (22%) | called by muse, mutect2, varscan2
- KCNQ4 | c.753C>T p.F251= | Silent (SNP) | VAF 28/356 reads (8%) | catalogued as rs1232415025, COSV61272046; called by muse, mutect2
- KDM2B | c.717C>T p.T239= | Silent (SNP) | VAF 54/264 reads (20%) | catalogued as rs782358759; called by muse, mutect2, varscan2
- KIAA1958 | c.1857T>C p.H619= | Silent (SNP) | VAF 25/411 reads (6%) | catalogued as rs1227356976; called by muse, mutect2
- KLHL34 | c.1380G>A p.P460= | Silent (SNP) | VAF 37/173 reads (21%) | catalogued as rs745809754, COSV65278706; called by muse, mutect2, varscan2
- KRT33B | c.237G>A p.R79= | Silent (SNP) | VAF 15/560 reads (3%) | called by muse, mutect2
- LAMA5 | c.1032G>A p.P344= | Silent (SNP) | VAF 80/336 reads (24%) | catalogued as rs766399151, COSV53369033; called by muse, mutect2, varscan2
- LHFPL4 | c.298C>T p.L100= | Silent (SNP) | VAF 54/306 reads (18%) | called by muse, mutect2, varscan2
- LRRC8B | c.144G>A p.T48= | Silent (SNP) | VAF 87/392 reads (22%) | catalogued as rs143539888; called by muse, mutect2, varscan2
- LYZL2 | c.303C>T p.S101= (on ENST00000375318; = p.S55= on NM_183058.3) | Silent (SNP) | VAF 48/176 reads (27%) | catalogued as rs757127551, COSV64684295; called by muse, mutect2, varscan2
- MEI1 | c.156G>A p.L52= | Silent (SNP) | VAF 12/248 reads (5%) | called by muse, mutect2
- MKRN3 | c.753T>A p.V251= | Silent (SNP) | VAF 10/295 reads (3%) | called by muse, mutect2
- MOS | c.549A>G p.L183= | Silent (SNP) | VAF 137/560 reads (24%) | called by muse, mutect2, varscan2
- MTA3 | c.1561C>T p.L521= (on ENST00000405094 / NM_001330442.2; = p.L464= on NM_001282755.1) | Silent (SNP) | VAF 40/203 reads (20%) | called by muse, mutect2, varscan2
- MYO1F | c.51C>T p.S17= | Silent (SNP) | VAF 44/215 reads (20%) | catalogued as rs777677983; called by muse, mutect2, varscan2
- MYOD1 | c.558G>A p.P186= | Silent (SNP) | VAF 57/211 reads (27%) | called by muse, mutect2, varscan2
- NAA11 | c.204G>A p.P68= | Silent (SNP) | VAF 36/182 reads (20%) | catalogued as rs762585511, COSV54513872, COSV54513940; called by muse, mutect2, varscan2
- NID1 | c.58C>T p.L20= | Silent (SNP) | VAF 30/145 reads (21%) | called by muse, mutect2, varscan2
- NOP10 | c.162G>A p.V54= | Silent (SNP) | VAF 124/634 reads (20%) | called by muse, mutect2, varscan2
- NPY2R | c.783G>A p.Q261= | Silent (SNP) | VAF 54/250 reads (22%) | called by muse, mutect2, varscan2
- NSD3 | c.1359G>A p.R453= | Silent (SNP) | VAF 80/307 reads (26%) | called by muse, mutect2, varscan2
- NUP85 | c.1218C>T p.Y406= | Silent (SNP) | VAF 66/265 reads (25%) | catalogued as rs781131003; called by muse, mutect2, varscan2
- OTUD7A | c.558G>A p.L186= | Silent (SNP) | VAF 25/81 reads (31%) | called by muse, mutect2, varscan2
- PCDH17 | c.921C>A p.G307= | Silent (SNP) | VAF 93/415 reads (22%) | called by muse, mutect2, varscan2
- PCDHB15 | c.2157G>A p.A719= | Silent (SNP) | VAF 105/391 reads (27%) | catalogued as rs1226095911, COSV50880401, COSV99178803; called by muse, mutect2, varscan2
- PCDHGA12 | c.258G>A p.T86= | Silent (SNP) | VAF 29/131 reads (22%) | catalogued as rs768036730; called by muse, mutect2, varscan2
- PLD1 | c.2016C>A p.S672= | Silent (SNP) | VAF 8/200 reads (4%) | called by muse, mutect2
- PMP22 | c.402C>T p.F134= | Silent (SNP) | VAF 123/529 reads (23%) | catalogued as rs536417866; called by muse, mutect2, varscan2
- PNMA8B | c.357G>A p.A119= | Silent (SNP) | VAF 53/250 reads (21%) | catalogued as rs572994007; called by muse, mutect2, varscan2
- PRAMEF19 | c.93G>A p.L31= | Silent (SNP) | VAF 83/369 reads (22%) | called by muse, mutect2, varscan2
- PRG4 | c.714G>A p.T238= | Silent (SNP) | VAF 58/242 reads (24%) | catalogued as rs754325528, COSV66625874; called by muse, mutect2, varscan2
- PRKCG | c.534C>T p.G178= | Silent (SNP) | VAF 93/423 reads (22%) | catalogued as rs367543207; ClinVar: likely benign; called by muse, mutect2, varscan2
- PXDNL | c.540C>T p.N180= | Silent (SNP) | VAF 12/137 reads (9%) | catalogued as rs780684959; called by muse, mutect2
- REM2 | c.561C>A p.T187= | Silent (SNP) | VAF 92/357 reads (26%) | catalogued as COSV99944555; called by muse, mutect2, varscan2
- RHOV | c.234G>T p.P78= | Silent (SNP) | VAF 62/268 reads (23%) | called by muse, mutect2, varscan2
- ROR2 | c.309G>A p.V103= | Silent (SNP) | VAF 123/578 reads (21%) | called by muse, mutect2, varscan2
- SATB1 | c.1875C>A p.P625= | Silent (SNP) | VAF 46/184 reads (25%) | called by muse, mutect2, varscan2
- SCARF1 | c.570C>T p.C190= | Silent (SNP) | VAF 8/204 reads (4%) | catalogued as rs1454097560; called by muse, mutect2
- SEPTIN9 | c.366C>T p.A122= (on ENST00000427177 / NM_001113491.2; = p.A104= on NM_006640.4) | Silent (SNP) | VAF 128/513 reads (25%) | catalogued as rs373004491; called by muse, mutect2, varscan2
- SFMBT2 | c.1167T>C p.H389= | Silent (SNP) | VAF 41/182 reads (23%) | called by muse, mutect2, varscan2
- SLC13A1 | c.537C>T p.H179= | Silent (SNP) | VAF 29/112 reads (26%) | catalogued as rs766450646, COSV52008059; called by muse, mutect2, varscan2
- SLC45A4 | c.2199G>A p.P733= (on ENST00000517878 / NM_001286646.2; = p.P682= on NM_001080431.2) | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as rs199863585; called by muse, mutect2
- SLC4A3 | c.1326G>A p.S442= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as rs1327363963, COSV56096904; called by muse, mutect2, varscan2
- SLC5A6 | c.178C>T p.L60= | Silent (SNP) | VAF 18/331 reads (5%) | called by muse, mutect2
- SLC7A5 | c.1185C>T p.S395= | Silent (SNP) | VAF 144/612 reads (24%) | catalogued as rs143124103; called by muse, mutect2, varscan2
- SMCR8 | c.99G>A p.P33= | Silent (SNP) | VAF 54/190 reads (28%) | catalogued as rs1303246985; called by muse, mutect2, varscan2
- SSH1 | c.306G>A p.A102= | Silent (SNP) | VAF 84/361 reads (23%) | catalogued as rs372563037; called by muse, mutect2, varscan2
- TBCCD1 | c.1014C>T p.N338= | Silent (SNP) | VAF 39/162 reads (24%) | catalogued as rs192772134; called by muse, mutect2, varscan2
- THAP3 | c.354C>T p.A118= (on ENST00000054650 / NM_001195753.1; = p.A125= on NM_138350.3) | Silent (SNP) | VAF 43/242 reads (18%) | catalogued as rs764806526; called by muse, mutect2, varscan2
- TIAL1 | c.261T>C p.S87= | Silent (SNP) | VAF 6/106 reads (6%) | catalogued as rs1476199818; called by muse, mutect2
- TM4SF1 | c.333A>T p.A111= | Silent (SNP) | VAF 41/227 reads (18%) | called by muse, mutect2, varscan2
- TNFRSF14 | c.630C>T p.L210= | Silent (SNP) | VAF 69/320 reads (22%) | catalogued as rs1285163368; called by muse, mutect2, varscan2
- TNK1 | c.960C>T p.G320= | Silent (SNP) | VAF 45/182 reads (25%) | called by muse, mutect2, varscan2
- TNXB | c.2520C>T p.I840= | Silent (SNP) | VAF 30/135 reads (22%) | catalogued as rs919704054, COSV100926463; called by muse, mutect2, varscan2
- TPST1 | c.915G>A p.K305= | Silent (SNP) | VAF 41/228 reads (18%) | called by muse, mutect2, varscan2
- TPT1 | c.438T>C p.V146= | Silent (SNP) | VAF 31/97 reads (32%) | called by muse, mutect2, varscan2
- TRBV3-1 | c.282T>C p.N94= | Silent (SNP) | VAF 32/124 reads (26%) | called by muse, varscan2
- TTN | c.36039C>T p.A12013= (on ENST00000591111; = p.A4589= on NM_003319.4) | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs917199946, COSV60116684; called by muse, mutect2, varscan2
- USP36 | c.1914C>T p.C638= | Silent (SNP) | VAF 78/352 reads (22%) | catalogued as rs776672459, COSV100361163; called by muse, mutect2, varscan2
- VARS2 | c.2331G>A p.P777= | Silent (SNP) | VAF 32/143 reads (22%) | catalogued as rs1187001363; called by muse, mutect2, varscan2
- ZFAT | c.1701C>T p.A567= | Silent (SNP) | VAF 34/116 reads (29%) | catalogued as rs1047154021; called by muse, mutect2, varscan2
- ZNF648 | c.1044G>A p.S348= | Silent (SNP) | VAF 90/387 reads (23%) | catalogued as rs866822851, COSV100374560, COSV60570923; called by muse, mutect2, varscan2
- ZNF674 | c.222G>A p.P74= | Silent (SNP) | VAF 13/372 reads (3%) | called by muse, mutect2
- ZNF777 | c.2490C>T p.G830= | Silent (SNP) | VAF 58/233 reads (25%) | catalogued as rs772956501, COSV56096781; called by muse, mutect2, varscan2
- ZPR1 | c.1041C>T p.L347= | Silent (SNP) | VAF 42/239 reads (18%) | catalogued as rs751920373; called by muse, mutect2, varscan2
- AAAS | c.1416+10C>A | Intron (SNP) | VAF 126/493 reads (26%) | called by muse, mutect2, varscan2
- ABCA2 | c.6013+13G>A | Intron (SNP) | VAF 44/170 reads (26%) | catalogued as rs368288084; called by muse, mutect2, varscan2
- AC244197.3 | c.-1911A>T | 5'UTR (SNP) | VAF 44/216 reads (20%) | called by muse, mutect2, varscan2
- ACKR1 | c.-22C>T | 5'UTR (SNP) | VAF 72/331 reads (22%) | catalogued as rs201809778, COSV63675029; called by muse, mutect2, varscan2
- ADAMTS13 | c.987+68dup | Intron (INS) | VAF 66/367 reads (18%) | catalogued as rs782744649; called by mutect2, pindel, varscan2
- ADAP1 | c.*16G>T | 3'UTR (SNP) | VAF 54/223 reads (24%) | catalogued as rs1450048181; called by muse, mutect2, varscan2
- AGA | c.*393del | 3'UTR (DEL) | VAF 4/36 reads (11%) | catalogued as rs920512602; called by pindel, varscan2
- AL512625.1 | n.277G>A | RNA (SNP) | VAF 32/604 reads (5%) | called by muse, mutect2
- ARHGAP33 | c.1568-17del | Intron (DEL) | VAF 23/96 reads (24%) | called by mutect2, pindel, varscan2
- ATG7 | c.2079+19591_2079+19593del | Intron (DEL) | VAF 4/38 reads (11%) | called by pindel, varscan2
- BET1 | c.201+74A>G | Intron (SNP) | VAF 14/41 reads (34%) | called by muse, varscan2
- C17orf107 | c.*1872G>T | 3'UTR (SNP) | VAF 132/548 reads (24%) | catalogued as COSV99545471; called by muse, mutect2, varscan2
- CCDC175 | c.2305+180C>T | Intron (SNP) | VAF 6/26 reads (23%) | called by muse, varscan2
- CCDC74A | c.295+401del | Intron (DEL) | VAF 83/337 reads (25%) | called by mutect2, varscan2
- CDK16 | c.-266C>T | 5'UTR (SNP) | VAF 66/297 reads (22%) | called by muse, mutect2, varscan2
- CGREF1 | chr2:27100431 G>A | 3'Flank (SNP) | VAF 7/189 reads (4%) | catalogued as rs1361078727; called by muse, mutect2
- CLDN5 | chr22:19524444 C>T | 5'Flank (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- CREB3L3 | c.-22G>A | 5'UTR (SNP) | VAF 76/323 reads (24%) | catalogued as rs777256377; called by muse, mutect2, varscan2
- DNAJC24 | c.112-6687T>C | Intron (SNP) | VAF 76/298 reads (26%) | catalogued as rs1432960368, COSV71938653; called by muse, mutect2, varscan2
- DOCK6 | c.45-31G>A | Intron (SNP) | VAF 15/72 reads (21%) | catalogued as rs369846752; called by muse, mutect2, varscan2
- ERAL1 | chr17:28861597 T>A | 3'Flank (SNP) | VAF 28/121 reads (23%) | called by muse, mutect2, varscan2
- FGF23 | c.*43C>T | 3'UTR (SNP) | VAF 26/114 reads (23%) | catalogued as rs769928972, COSV52978253; called by muse, mutect2, varscan2
- GANC | c.*2271G>A | 3'UTR (SNP) | VAF 30/127 reads (24%) | called by muse, mutect2, varscan2
- GRB7 | c.-27G>A | 5'UTR (SNP) | VAF 58/198 reads (29%) | catalogued as rs749753011, COSV58447750; called by muse, mutect2, varscan2
- GSDMD | c.410+88dup | Intron (INS) | VAF 23/123 reads (19%) | called by mutect2, pindel, varscan2
- HLA-G | c.-2G>T | 5'UTR (SNP) | VAF 62/316 reads (20%) | catalogued as COSV100827072; called by muse, mutect2, varscan2
- IFI27L1 | c.-98+6833G>A | Intron (SNP) | VAF 50/263 reads (19%) | catalogued as rs150313230; called by muse, mutect2, varscan2
- JPH3 | c.2167-1237G>T | Intron (SNP) | VAF 52/277 reads (19%) | called by muse, mutect2, varscan2
- KIAA1841 | c.1837-3del | Intron (DEL) | VAF 64/268 reads (24%) | catalogued as rs754110263; called by mutect2, varscan2
- KIAA1958 | c.1172-26997C>T | Intron (SNP) | VAF 77/281 reads (27%) | called by muse, mutect2, varscan2
- KLF6 | c.*482del | 3'UTR (DEL) | VAF 43/195 reads (22%) | catalogued as rs375375286; called by mutect2, varscan2
- KRTAP2-2 | c.*141C>T | 3'UTR (SNP) | VAF 22/126 reads (17%) | catalogued as COSV101195314; called by muse, varscan2
- LINC02610 | n.2858C>G | RNA (SNP) | VAF 12/282 reads (4%) | called by muse, mutect2
- MACROD2 | c.859+756G>T | Intron (SNP) | VAF 70/338 reads (21%) | called by muse, varscan2
- MALRD1 | c.5030-2354G>A | Intron (SNP) | VAF 42/157 reads (27%) | catalogued as rs1269633323; called by muse, mutect2, varscan2
- MDM1 | c.498+105_498+107del | Intron (DEL) | VAF 16/52 reads (31%) | catalogued as rs757256737; called by pindel, varscan2
- MIR424 | chrX:134546576 G>A | 3'Flank (SNP) | VAF 6/57 reads (11%) | called by muse, mutect2, varscan2
- MLIP | c.613-11026T>G | Intron (SNP) | VAF 18/342 reads (5%) | called by muse, mutect2
- NEDD9 | c.12+21dup | Intron (INS) | VAF 45/193 reads (23%) | catalogued as rs759178609; called by mutect2, varscan2
- NVL | c.2183-6718del | Intron (DEL) | VAF 26/245 reads (11%) | catalogued as rs573934358; called by mutect2, varscan2
- OR52B1P | n.338T>C | RNA (SNP) | VAF 51/310 reads (16%) | called by muse, mutect2, varscan2
- OR7D1P | n.920G>T | RNA (SNP) | VAF 26/105 reads (25%) | called by muse, mutect2, varscan2
- PALLD | c.1965-12574C>G | Intron (SNP) | VAF 66/225 reads (29%) | catalogued as rs763225090, COSV54984423; called by muse, mutect2, varscan2
- PCGF3 | c.*3G>T | 3'UTR (SNP) | VAF 39/170 reads (23%) | called by muse, mutect2, varscan2
- PGRMC1 | c.-2T>C | 5'UTR (SNP) | VAF 67/318 reads (21%) | called by muse, mutect2, varscan2
- PGRMC1 | c.-1C>A | 5'UTR (SNP) | VAF 68/322 reads (21%) | called by muse, mutect2, varscan2
- PLCZ1 | c.-94A>T | 5'UTR (SNP) | VAF 55/253 reads (22%) | catalogued as rs768962770; called by muse, mutect2, varscan2
- PPP2R3A | c.1996-3738C>T | Intron (SNP) | VAF 77/319 reads (24%) | catalogued as rs753407993; called by muse, mutect2, varscan2
- PSD3 | c.2175+2447C>T | Intron (SNP) | VAF 57/257 reads (22%) | called by muse, mutect2, varscan2
- PSEN2 | c.-20-5del | Intron (DEL) | VAF 66/304 reads (22%) | catalogued as COSV60914679; called by mutect2, varscan2
- PSME2 | c.232-13del | Intron (DEL) | VAF 38/151 reads (25%) | catalogued as rs766572157; called by mutect2, pindel, varscan2
- QKI | c.935-53del | Intron (DEL) | VAF 74/267 reads (28%) | catalogued as rs372217972; called by mutect2, pindel, varscan2
- RAB18 | c.*3641del | 3'UTR (DEL) | VAF 37/156 reads (24%) | catalogued as rs771049979; called by mutect2, varscan2
- RAD50 | c.1793+814G>A | Intron (SNP) | VAF 35/179 reads (20%) | called by muse, mutect2, varscan2
- RAD51D | c.263+1564C>T | Intron (SNP) | VAF 41/190 reads (22%) | called by muse, mutect2, varscan2
- RBM3 | c.211-68G>A | Intron (SNP) | VAF 105/415 reads (25%) | called by muse, mutect2, varscan2
- RBM48 | c.1017+35G>A | Intron (SNP) | VAF 31/117 reads (26%) | catalogued as rs1164725412, COSV56004175; called by muse, mutect2, varscan2
- RFC4 | c.801+45del | Intron (DEL) | VAF 39/216 reads (18%) | called by mutect2, pindel, varscan2
- RHOT1 | c.-133G>A | 5'UTR (SNP) | VAF 6/22 reads (27%) | catalogued as rs1226023803; called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159896 G>A | 5'Flank (SNP) | VAF 15/70 reads (21%) | catalogued as rs1413811503; called by muse, mutect2, varscan2
- RPL34-DT | n.260G>T | RNA (SNP) | VAF 43/214 reads (20%) | called by muse, mutect2, varscan2
- RSPH9 | c.-40_-38del | 5'UTR (DEL) | VAF 65/270 reads (24%) | called by mutect2, pindel, varscan2
- RTN1 | c.1766-22970C>A | Intron (SNP) | VAF 66/264 reads (25%) | catalogued as rs1449638556; called by muse, mutect2, varscan2
- SEMA4A | c.811-22del | Intron (DEL) | VAF 24/122 reads (20%) | called by mutect2, pindel, varscan2
- SNRPD3 | c.*73C>T | 3'UTR (SNP) | VAF 67/337 reads (20%) | called by muse, mutect2, varscan2
- SNX29 | c.1402+9059C>A | Intron (SNP) | VAF 10/208 reads (5%) | called by muse, mutect2
- STX17 | c.190-5287del | Intron (DEL) | VAF 11/57 reads (19%) | called by mutect2, pindel, varscan2
- STX1B | c.*9del | 3'UTR (DEL) | VAF 20/108 reads (19%) | catalogued as rs750392809; called by mutect2, varscan2
- TGFBR3 | c.*2493del | 3'UTR (DEL) | VAF 22/116 reads (19%) | catalogued as rs1315164511; called by mutect2, pindel, varscan2
- TNRC18 | c.*621C>T | 3'UTR (SNP) | VAF 7/47 reads (15%) | catalogued as rs759248277; called by muse, mutect2, varscan2
- TTC8 | c.115-2449G>A | Intron (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- UBE3A | c.2508-19del | Intron (DEL) | VAF 12/112 reads (11%) | catalogued as rs549180002; called by mutect2, pindel, varscan2
- VAPB | c.*2949C>T | 3'UTR (SNP) | VAF 115/473 reads (24%) | catalogued as rs1476977232; called by muse, mutect2, varscan2
- XIAP | c.*6543dup | 3'UTR (INS) | VAF 27/117 reads (23%) | called by mutect2, varscan2
